Gene-level copy-number profile of tumor specimen TCGA-AO-A03V-01A from TCGA case TCGA-AO-A03V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 41.8 years (15,284 days).
Specimen TCGA-AO-A03V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6c95b250-69e7-444d-8087-731383aaff4f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A03V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2618c286-c4c6-443b-9b28-951ba90c0592

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 22; copy number 2: 10,914; copy number 3: 1,449; copy number 4: 36,803; copy number 5: 2,331; copy number 6: 3,697; copy number 7: 860; copy number 8: 588; copy number 9: 708; copy number 10: 803; copy number 11: 143; copy number 12: 269; copy number 13: 105; copy number 14: 243; copy number 15: 167; copy number 16: 39; copy number 17: 84; copy number 18: 127; copy number 19: 325; copy number 20: 49; copy number 22: 6; copy number 23: 16; copy number 24: 6; copy number 25: 25; copy number 26: 2; copy number 37: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A03V-01A-11D-A111-01): tumor purity 0.73, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:122,374,696–122,699,846, 9 genes: PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:12,201,600–12,395,177, 2 genes: AC005244.2, AC084167.1.
- chr17:12,665,890–12,991,643, 5 genes (within-gene range 0–2): MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,125 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:10,478,037–11,904,446, 19 genes, copy number 9: MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P.
- chr5:13,250,235–14,532,128, 7 genes, copy number 10–12 (within-gene range 4–12): RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:18,547,312–29,265,940, 100 genes, copy number 10–13 (broad region; genes not listed).
- chr5:39,520,398–45,895,970, 98 genes, copy number 9 (broad region; genes not listed).
- chr10:49,551,308–49,970,203, 8 genes, copy number 9 (within-gene range 6–9): HMGB1P50, CHAT, SLC18A3, C10orf53, OGDHL, MAPK6P6, RPL21P89, PARG.
- chr10:56,595,963–56,596,031, 1 gene, copy number 9: AC025039.1.
- chr10:65,570,338–68,527,523, 36 genes, copy number 13–25 (within-gene range 3–40): LINC01515, CTNNA3, AC022017.1, AL607023.1, LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5, MYPN, RN7SKP202, ATOH7, LINC02640, KRT19P4, PBLD, HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA.
- chr10:72,367,327–76,560,168, 121 genes, copy number 16–18 (within-gene range 3–18) (broad region; genes not listed).
- chr10:78,696,062–79,067,895, 3 genes, copy number 14: AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:114,043,866–117,753,329, 61 genes, copy number 11–14 (broad region; genes not listed).
- chr10:120,759,898–122,345,793, 25 genes, copy number 15–23 (within-gene range 2–23): WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P.
- chr10:128,096,659–129,380,753, 8 genes, copy number 22–26: MKI67, LINC01163, AL390763.1, LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1.
- chr13:92,701,389–96,053,482, 38 genes, copy number 9 (within-gene range 4–9): GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1, DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.
- chr13:100,338,982–112,887,168, 155 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr15:61,852,389–62,060,473, 1 gene, copy number 10 (within-gene range 5–10): VPS13C.
- chr15:62,060,503–74,516,959, 320 genes, copy number 10 (broad region; genes not listed).
- chr15:87,325,829–93,569,483, 175 genes, copy number 9–17 (within-gene range 7–17) (broad region; genes not listed).
- chr15:93,905,405–94,107,938, 2 genes, copy number 15 (within-gene range 7–15): LINC01581, AC104390.1.
- chr15:95,186,634–96,327,361, 17 genes, copy number 10–19 (within-gene range 8–19): LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157.
- chr15:98,282,075–101,933,350, 99 genes, copy number 12 (broad region; genes not listed).
- chr17:3,088,484–3,386,317, 13 genes, copy number 13 (within-gene range 2–13): OR1D2, OR1E3, OR1G1, AC090282.1, OR1P1, OR1A2, OR1A1, OR1D4, OR1D3P, OR3A2, OR3A1, OR3A4P, AC087498.1.
- chr17:12,549,764–12,642,854, 2 genes, copy number 9 (within-gene range 0–9): LINC00670, AC068442.1.
- chr17:26,981,694–30,577,000, 197 genes, copy number 10–12 (broad region; genes not listed).
- chr17:82,273,748–82,945,914, 38 genes, copy number 9–11 (within-gene range 2–11): AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750.
- chr18:12,201,982–13,764,556, 51 genes, copy number 9–13: AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT.
- chr18:38,655,209–39,034,110, 3 genes, copy number 9: AC100781.1, RN7SKP182, RNU6-706P.
- chr18:41,341,319–44,342,315, 18 genes, copy number 9: AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1.
- chr18:55,222,185–67,137,751, 174 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:34,359,480–36,535,235, 149 genes, copy number 9–37 (within-gene range 5–37) (broad region; genes not listed).
- chr19:48,547,637–48,961,798, 29 genes, copy number 19 (within-gene range 2–19): AC008403.3, SULT2B1, FAM83E, SPACA4, RPL18, AC022154.1, SPHK2, DBP, CA11, SEC1P, NTN5, FUT2, MAMSTR, RASIP1, IZUMO1, FUT1, FGF21, RNU6-317P, BCAT2, AC026803.3, HSD17B14, PLEKHA4, PPP1R15A, TULP2, NUCB1, NUCB1-AS1, AC026803.1, DHDH, BAX.
- chr19:49,453,225–54,257,301, 390 genes, copy number 14–19 (within-gene range 2–19) (broad region; genes not listed).
- chr19:54,521,723–58,605,223, 297 genes, copy number 10–19 (broad region; genes not listed).
- chr20:3,888,239–17,226,146, 189 genes, copy number 10 (broad region; genes not listed).
- chr20:37,975,156–39,039,723, 44 genes, copy number 9–14: RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19.
- chr20:48,624,252–49,244,077, 10 genes, copy number 13: PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27.
- chr20:49,721,949–50,321,342, 24 genes, copy number 9: RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:50,999,370–54,269,542, 48 genes, copy number 11–20: AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:57,895,394–58,715,410, 16 genes, copy number 11 (within-gene range 4–11): AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1.
- chr20:59,123,381–61,940,617, 32 genes, copy number 13–24 (within-gene range 4–24): ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.
- chr20:62,642,503–64,313,132, 103 genes, copy number 19 (within-gene range 4–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
